Somatic mutation profile of tumor specimen C3L-07438-61 (aliquot CPT0447860002) from CPTAC case C3L-07438, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 79.5 years (29,050 days).
Specimen C3L-07438-61: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a5196fe-eecb-4c1f-8a44-5ba0ed561be6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07438-50 (Buccal Cell Normal), aliquot CPT0447900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2136e618-71d0-435c-a7d6-44f16c07b7b6

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 2, Silent 2, Splice Region 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 108/229 reads (47%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASXL2 | c.38G>A p.W13* | Nonsense Mutation (SNP) | VAF 114/208 reads (55%) | catalogued as COSV55455353; called by muse, mutect2, varscan2
- DNAJC16 | c.1680C>T p.S560= | Splice Region (SNP) | VAF 94/191 reads (49%) | catalogued as rs148700636; called by muse, mutect2, varscan2
- PRKAA2 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 48/106 reads (45%) | catalogued as COSV64803149; called by muse, mutect2, varscan2
- KCNV2 | c.1621C>A p.P541T | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYB | c.30_31dup p.S11Ifs*42 | Frame Shift Ins (INS) | VAF 24/124 reads (19%) | called by mutect2, varscan2
- OR8U1 | c.863T>C p.L288S | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by mutect2, varscan2
- PLCG1 | c.1969G>C p.V657L | Missense Mutation (SNP) | VAF 189/382 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAPPC8 | c.3310T>G p.F1104V | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.143); called by muse, varscan2
- VN1R2 | c.840C>A p.A280= | Silent (SNP) | VAF 96/192 reads (50%) | catalogued as COSV59039078; called by muse, mutect2, varscan2
- ZNF14 | c.1857A>G p.Q619= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs1307469088; called by muse, mutect2
- SPIDR | c.-5C>A | 5'UTR (SNP) | VAF 21/32 reads (66%) | called by muse, mutect2, varscan2
